MMRF case MMRF_2335 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a2c46427-006d-46bf-b499-0320b3e9c7eb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 264 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.9 years (23,700 days); ISS stage: III; Days to last known disease status: 264 days; Days to last follow up: 264 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 264 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 264.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 6.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 211 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.14 mg/dL; Immunoglobulin G 93.1 g/L; Immunoglobulin A 0.455 g/L; Immunoglobulin M 0.0665 g/L; Beta 2 Microglobulin 9.99 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.14 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 95.5 µmol/L; Calcium 2.65 mmol/L; Albumin 44.4 g/L; Total Protein 13.4 g/dL; Glucose 6.49 mmol/L.
- Day 92 (ECOG 1): M Protein 0.79 g/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 3.67 g/L; Immunoglobulin M 0.383 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.95 ×10⁹/L; Absolute Neutrophil 3.66 ×10⁹/L; Platelets 390 ×10⁹/L; Creatinine 111 µmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.9 g/dL; Glucose 7.87 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.27 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 3.29 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 5.33 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 350 ×10⁹/L; Creatinine 111 µmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 7.59 mmol/L.

Other clinical attributes
- Day -6: Weight: 80 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2335_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2335_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
